CCDI case PBCFDV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/06bf99b7-1c3b-46f4-b96e-79038a02dbd1

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,072 days).

Biospecimens (3 samples)
- Sample 0DQJIK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQJIQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQJIW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
